Somatic mutation profile of tumor specimen TCGA-CJ-5681-01A (aliquot TCGA-CJ-5681-01A-11D-1534-10) from TCGA case TCGA-CJ-5681, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 44.1 years (16,121 days).
Specimen TCGA-CJ-5681-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67d1c996-4b09-491a-afcd-c709f60d8ce3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-5681-11A (Solid Tissue Normal), aliquot TCGA-CJ-5681-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc45b2db-1187-4fca-985d-d5ace3999c23

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Frame Shift Del 4, Splice Site 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF2 | c.2309C>T p.S770F | Missense Mutation (SNP) | VAF 93/241 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV53980151, COSV53986252; called by muse, mutect2, varscan2
- CHD7 | c.4823G>A p.R1608K | Missense Mutation (SNP) | VAF 84/246 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as COSV71108496; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs751548647; called by mutect2, varscan2
- CRYGA | c.459G>C p.R153S | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.195); catalogued as rs201293779, COSV58016124; called by muse, mutect2, varscan2
- FAM71F2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV66351982; called by muse, mutect2, varscan2
- KIF27 | c.3064G>T p.V1022F | Missense Mutation (SNP) | VAF 143/717 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as COSV52826434; called by muse, mutect2, varscan2
- LILRB1 | c.632G>A p.R211H (on ENST00000427581; = p.R175H on NM_006669.6) | Missense Mutation (SNP) | VAF 99/297 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs112916853, COSV61116962, COSV61117136, COSV61121229; called by muse, varscan2
- MSI1 | c.732C>T p.P244= | Splice Region (SNP) | VAF 63/172 reads (37%) | catalogued as rs140182426; called by muse, mutect2, varscan2
- MZT1 | c.181T>G p.S61A | Missense Mutation (SNP) | VAF 215/529 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.921); catalogued as COSV64697729; called by muse, mutect2, varscan2
- NPC1 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV52577524; called by muse, mutect2, varscan2
- NPC1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs1448333382, COSV52577535; called by muse, mutect2, varscan2
- NPRL2 | c.448+1G>C p.X150_splice | Splice Site (SNP) | VAF 29/46 reads (63%) | catalogued as COSV51600955, COSV51604873; called by muse, mutect2, varscan2
- OR5W2 | c.210T>A p.D70E | Missense Mutation (SNP) | VAF 151/347 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV60615267; called by muse, mutect2, varscan2
- PGLYRP3 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 225/646 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV51949628; called by muse, mutect2, varscan2
- PLOD3 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV56182041; called by muse, mutect2, varscan2
- RBM39 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 137/428 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs1288750952, COSV53614574; called by muse, mutect2, varscan2
- SLC16A9 | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766612422, COSV101264529, COSV68098618; called by muse, mutect2, varscan2
- SOBP | c.46A>G p.S16G | Missense Mutation (SNP) | VAF 102/298 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV57996933; called by muse, varscan2
- STK11 | c.762del p.F255Sfs*32 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | catalogued as CM981869, COSV58825310; called by mutect2, varscan2
- ZFHX3 | c.5456G>T p.S1819I | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as rs1274620713, COSV51713548; called by muse, mutect2, varscan2
- GLI2 | c.237_240del p.V80Tfs*20 | Frame Shift Del (DEL) | VAF 59/196 reads (30%) | called by mutect2, pindel, varscan2
- ZCCHC14 | c.276_280del p.H92Qfs*5 (on ENST00000268616; = p.H229Qfs*5 on NM_015144.3) | Frame Shift Del (DEL) | VAF 120/350 reads (34%) | called by mutect2, pindel, varscan2
- ZNF84 | c.266T>A p.M89K | Missense Mutation (SNP) | VAF 172/427 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC124 | c.654C>T p.P218= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV71490350; called by muse, mutect2, varscan2
- PLOD3 | c.117G>T p.L39= | Silent (SNP) | VAF 54/108 reads (50%) | catalogued as COSV56182068; called by muse, mutect2, varscan2
- SCPEP1 | c.147C>G p.A49= | Silent (SNP) | VAF 112/334 reads (34%) | catalogued as rs376140010, COSV51853745; called by muse, mutect2
- SEMA3A | c.870T>C p.R290= | Silent (SNP) | VAF 157/428 reads (37%) | catalogued as COSV54865698; called by muse, mutect2, varscan2
- ZNF185 | c.411C>T p.T137= | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as COSV59275055; called by muse, mutect2, varscan2
- DST | c.4297-2594A>G | Intron (SNP) | VAF 36/105 reads (34%) | catalogued as COSV55005874; called by muse, mutect2, varscan2
